Somatic mutation profile of tumor specimen TCGA-CN-6010-01A (aliquot TCGA-CN-6010-01A-11D-1683-08) from TCGA case TCGA-CN-6010, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.3 years (19,475 days).
Specimen TCGA-CN-6010-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e746abbd-3c96-4416-9bf0-d627b55f11ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6010-10A (Blood Derived Normal), aliquot TCGA-CN-6010-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20c17e80-6e6e-4c29-854b-e32048ab4e2c

The open-access MAF lists 140 somatic variants for this specimen: 105 protein-altering or splice-affecting, 30 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 30, Nonsense Mutation 8, Splice Site 3, Intron 3, Splice Region 2, RNA 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 18/47 reads (38%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM1412038, COSV55944050; called by mutect2, varscan2
- ADGRV1 | c.8794G>T p.A2932S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.297); catalogued as COSV101316647; called by muse, mutect2, varscan2
- ADSS2 | c.1213C>A p.L405I | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as COSV100836922; called by mutect2, varscan2
- AK7 | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.17); catalogued as COSV99967601; called by muse, mutect2, varscan2
- ALG10 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV99848389; called by muse, mutect2
- ALMS1 | c.11550A>G p.V3850= | Splice Region (SNP) | VAF 38/241 reads (16%) | catalogued as rs45630561, COSV100043963; called by muse, mutect2, varscan2
- AMY2A | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs1308572870, COSV101340684; called by mutect2, varscan2
- ANO5 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs745972421, COSV61083410; called by muse, mutect2, varscan2
- ARID4B | c.2129C>T p.S710F | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99936477; called by muse, mutect2, varscan2
- ASGR2 | c.116T>C p.F39S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99643193; called by muse, mutect2, varscan2
- ATIC | c.931A>G p.R311G | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99378269; called by muse, mutect2, varscan2
- CACNG8 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); catalogued as rs1034925737, COSV54414296; called by muse, mutect2
- CCDC14 | c.1127A>T p.D376V (on ENST00000488653; = p.D328V on NM_022757.5) | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV100113495; called by muse, mutect2, varscan2
- CDH11 | c.1639C>T p.R547* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as rs1177793851, COSV51767131, COSV99219998; called by muse, varscan2
- CDR2 | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99193583; called by muse, mutect2, varscan2
- CHD8 | c.2908G>T p.E970* (on ENST00000646647 / NM_001170629.2; = p.E691* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as rs1555315362, COSV101303228; called by muse, mutect2
- CHRDL1 | c.1329G>T p.E443D (on ENST00000372045; = p.E449D on NM_145234.4) | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99488783; called by mutect2, varscan2
- CNTNAP2 | c.1711C>G p.Q571E | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100673564; called by muse, mutect2, varscan2
- CNTNAP4 | c.1545T>A p.C515* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100273622; called by muse, mutect2, varscan2
- COL16A1 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99595638; called by muse, mutect2, varscan2
- CPED1 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV100121613; called by muse, mutect2, varscan2
- CPS1 | c.4130T>A p.V1377E | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99244331; called by muse, varscan2
- CRB1 | c.863G>A p.C288Y | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV66345361; called by mutect2, varscan2
- CXXC5 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1283965885, COSV56796094; called by mutect2, varscan2
- DCLRE1B | c.1462A>G p.K488E | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100849872; called by muse, mutect2, varscan2
- DDHD1 | c.1180A>G p.K394E (on ENST00000323669; = p.K591E on NM_030637.3) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs1451746119, COSV100080182; called by muse, mutect2, varscan2
- DGKD | c.238C>T p.R80* (on ENST00000264057 / NM_152879.3; = p.R36* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/92 reads (30%) | catalogued as rs777123239, COSV99897786; called by muse, mutect2, varscan2
- DHCR7 | c.1366G>A p.G456S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs201847193, CM154264, COSV100832167; ClinVar: uncertain significance; called by mutect2, varscan2
- DPP10 | c.986A>T p.N329I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100072605; called by muse, mutect2, varscan2
- ELAVL2 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV56368718, COSV99807403; called by muse, mutect2
- FASTKD2 | c.1529A>T p.Y510F | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV99379314; called by muse, varscan2
- FLG | c.10096C>G p.Q3366E | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.056); catalogued as COSV100912346; called by muse, mutect2, varscan2
- FRMPD2 | c.1870A>T p.S624C | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100564271; called by muse, mutect2, varscan2
- HAVCR1 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.16); catalogued as COSV100208650; called by muse, mutect2, varscan2
- HDAC9 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV101287831; called by muse, mutect2
- HSPB9 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs781941486, COSV99863428, COSV99863715, COSV99863719; called by muse, mutect2, varscan2
- IQUB | c.2125C>T p.P709S | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100227408; called by muse, mutect2, varscan2
- KCNH8 | c.1915C>A p.L639I | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100111148; called by mutect2, varscan2
- KEAP1 | c.533A>T p.Q178L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99408354; called by muse, mutect2, varscan2
- KIF4B | c.806G>A p.C269Y | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1306146324, COSV101469419, COSV99069629; called by mutect2, varscan2
- KYAT3 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.136); catalogued as COSV99557113; called by muse, mutect2, varscan2
- LCE1C | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.866); catalogued as rs1369001286, COSV100908420; called by mutect2, varscan2
- LMBRD2 | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99683316; called by muse, mutect2, varscan2
- LRRC17 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1462096736, COSV50863979; called by mutect2, varscan2
- LTBR | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99965437; called by muse, mutect2, varscan2
- MCOLN2 | c.1613A>T p.E538V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99394344; called by mutect2, varscan2
- METTL25 | c.1597T>A p.Y533N | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99942746; called by mutect2, varscan2
- MON2 | c.2473C>T p.Q825* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV54803273; called by muse, mutect2, varscan2
- MTNR1A | c.665A>T p.K222I | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100208348; called by mutect2, varscan2
- MYH11 | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs746982396, COSV100260468; called by muse, mutect2, varscan2
- NEFH | c.1689G>T p.E563D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100151885; called by mutect2, varscan2
- NKAPL | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV100642596, COSV59199217; called by muse, mutect2, varscan2
- NR0B1 | c.1169-2A>T p.X390_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100973486; called by muse, mutect2
- NUP98 | c.3059C>T p.A1020V (on ENST00000359171 / NM_001365126.1; = p.A1003V on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100263612; called by mutect2, varscan2
- OR2T4 | c.994G>C p.A332P | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100822652; called by muse, mutect2, varscan2
- OR4D11 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100506651; called by mutect2, varscan2
- PCDH10 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99994671; called by muse, mutect2, varscan2
- PCDH11X | c.1519C>A p.P507T | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100015821; called by mutect2, varscan2
- PCDHA5 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV65359173; called by mutect2, varscan2
- PCDHB11 | c.92G>A p.W31* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV53377581, COSV99503462; called by mutect2, varscan2
- PEG3 | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99690679; called by muse, mutect2, varscan2
- PEX2 | c.46A>T p.R16* | Nonsense Mutation (SNP) | VAF 15/129 reads (12%) | catalogued as COSV100824969; called by mutect2, varscan2
- PIKFYVE | c.4162C>T p.L1388F | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100011560; called by muse, varscan2
- PLA2G4A | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as rs892336472, COSV66556563; called by mutect2, varscan2
- PLAA | c.2321A>T p.K774M | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101263585; called by mutect2, varscan2
- POSTN | c.2473+1G>A p.X825_splice | Splice Site (SNP) | VAF 32/140 reads (23%) | catalogued as COSV101123524; called by muse, mutect2, varscan2
- PRAMEF2 | c.803A>G p.H268R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); catalogued as COSV99535785; called by muse, mutect2, varscan2
- PRB3 | c.910C>G p.Q304E (on ENST00000381842; = p.Q346E on NM_006249.5) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV99686132; called by muse, mutect2, varscan2
- PRH1 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as COSV101457521; called by mutect2, varscan2
- PRSS1 | c.721A>T p.N241Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs141554682; called by mutect2, varscan2
- PSG8 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60609273; called by muse, mutect2, varscan2
- PTPRM | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs373023204; called by mutect2, varscan2
- RBAK | c.667C>G p.H223D | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as rs753740667, COSV100806586, COSV100806796; called by muse, mutect2, varscan2
- RELN | c.4690C>G p.L1564V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100632525; called by muse, varscan2
- RHBDL3 | c.643C>A p.L215M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV99284000; called by mutect2, varscan2
- RNF180 | c.232-2A>T p.X78_splice | Splice Site (SNP) | VAF 30/146 reads (21%) | catalogued as COSV99685013; called by mutect2, varscan2
- SCRN1 | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54132678, COSV99621917; called by muse, mutect2, varscan2
- SHC2 | c.823A>G p.R275G | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52747558; called by muse, mutect2, varscan2
- SLC35F4 | c.350G>T p.G117V (on ENST00000339762 / NM_001352015.2; = p.G81V on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100334308, COSV60264722; called by mutect2, varscan2
- SLC35G5 | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs745921732; called by muse, mutect2, varscan2
- SORCS1 | c.1053G>T p.Q351H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.26); catalogued as COSV53896843, COSV99550911; called by muse, mutect2, varscan2
- SORCS1 | c.1052A>C p.Q351P | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as COSV99550913; called by muse, mutect2, varscan2
- SPATA6L | c.893C>A p.S298Y (on ENST00000461761 / NM_001353484.2; = p.S240Y on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.439); catalogued as COSV101121934; called by muse, mutect2, varscan2
- SPOCD1 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs935329334, COSV99930418; called by muse, mutect2, varscan2
- SUGP1 | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99895663; called by muse, mutect2, varscan2
- SYNE2 | c.1287A>T p.L429F | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV59942143; called by muse, mutect2
- TFB1M | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs765856279, COSV100905264, COSV65698737; called by muse, mutect2, varscan2
- TNIK | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV52694880, COSV99460015; called by muse, mutect2, varscan2
- TRAPPC12 | c.1063G>C p.D355H | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100161049; called by muse, mutect2, varscan2
- TTC3 | c.1781A>C p.E594A | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV100696114; called by muse, varscan2
- TUBG1 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV52220788, COSV99258977; called by muse, varscan2
- UBTD2 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV101196396; called by muse, mutect2, varscan2
- WDR26 | c.1067A>G p.Y356C (on ENST00000414423 / NM_001379403.1; = p.Y256C on NM_025160.7) | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.075); catalogued as rs1484657903, COSV99691620; called by muse, mutect2, varscan2
- XIRP1 | c.3328G>T p.D1110Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100453691, COSV100454043; called by mutect2, varscan2
- XIRP2 | c.9452T>A p.V3151E (on ENST00000628543; = p.V3326E on NM_152381.6) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV54740408, COSV99748268; called by muse, mutect2
- XRN2 | c.2036T>C p.L679P | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.795); catalogued as rs1184258558, COSV101018705; called by muse, mutect2, varscan2
- ZNF577 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as COSV100031343; called by muse, mutect2, varscan2
- ZNF649 | c.599A>G p.H200R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100031344; called by muse, varscan2
- CCDC63 | c.62A>T p.K21M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by mutect2, varscan2
- LILRB3 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by mutect2, varscan2
- MRC1 | c.2569C>A p.Q857K | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PDZRN4 | c.2264C>A p.S755Y (on ENST00000402685 / NM_001164595.2; = p.S497Y on NM_013377.4) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SIN3B | c.1810del p.D605Tfs*5 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- UPF2 | c.2287dup p.T763Nfs*23 | Frame Shift Ins (INS) | VAF 14/117 reads (12%) | called by mutect2, pindel, varscan2
- AHNAK | c.3963C>A p.P1321= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as COSV99949955; called by mutect2, varscan2
- ANKRD28 | c.252T>C p.S84= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- ANPEP | c.1107C>T p.F369= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs367827322; called by mutect2, varscan2
- ATP13A4 | c.2049G>C p.L683= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as COSV100710803, COSV61328166; called by muse, mutect2, varscan2
- CEP85L | c.2109A>G p.K703= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as COSV100874404; called by muse, mutect2, varscan2
- CLSTN2 | c.1401C>A p.T467= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV71721777; called by mutect2, varscan2
- COL4A4 | c.2685T>C p.D895= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100307889, COSV61632547; called by muse, mutect2
- ECE1 | c.1365C>T p.T455= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99942455; called by muse, mutect2, varscan2
- FLNC | c.5955G>A p.S1985= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs777895128, COSV100368896; ClinVar: uncertain significance; called by mutect2, varscan2
- GAL3ST3 | c.693G>A p.V231= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV61749795; called by mutect2, varscan2
- GRIP1 | c.2703C>T p.C901= (on ENST00000359742 / NM_001379345.1; = p.C849= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 40/249 reads (16%) | catalogued as rs369702702; called by muse, mutect2, varscan2
- HDAC4 | c.894C>T p.S298= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs777669264, COSV100614386; called by muse, mutect2, varscan2
- HEATR9 | c.903G>A p.Q301= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- LARP1 | c.1533C>T p.Y511= (on ENST00000518297 / NM_033551.3; = p.Y434= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100304165; called by muse, mutect2, varscan2
- LDB2 | c.219T>C p.D73= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100455078; called by muse, varscan2
- MUC17 | c.6573T>C p.P2191= | Silent (SNP) | VAF 24/229 reads (10%) | catalogued as COSV100075375; called by muse, mutect2, varscan2
- OR11L1 | c.468C>T p.G156= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV63313763; called by muse, mutect2, varscan2
- PCDHGA4 | c.1002A>T p.I334= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99548468; called by muse, mutect2, varscan2
- PTPRG | c.867C>T p.T289= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99872875; called by muse, mutect2, varscan2
- PTPRH | c.315A>T p.G105= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV99671518; called by mutect2, varscan2
- PTPRZ1 | c.6903A>C p.A2301= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV101100904; called by muse, mutect2, varscan2
- RGL1 | c.2247G>A p.T749= (on ENST00000360851 / NM_001297672.2; = p.T784= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs764289440, COSV58983478; called by muse, mutect2, varscan2
- RNF213 | c.7416C>T p.F2472= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs143772929; called by mutect2, varscan2
- RRN3 | c.1710A>C p.S570= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV99549171; called by muse, mutect2, varscan2
- SAGE1 | c.2499A>G p.K833= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV100188035; called by muse, mutect2, varscan2
- SALL1 | c.2862C>T p.S954= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs775808496, COSV51754492; called by mutect2, varscan2
- SECISBP2 | c.1680C>T p.D560= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs757239264, COSV100368914; called by mutect2, varscan2
- SLC22A5 | c.441C>T p.S147= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as COSV99810250; called by muse, mutect2, varscan2
- SPEF2 | c.261A>C p.T87= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV99214980; called by muse, mutect2, varscan2
- TGM7 | c.145C>A p.R49= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV101476906; called by muse, mutect2, varscan2
- DHRS4L1 | n.437+4113C>T | Intron (SNP) | VAF 19/132 reads (14%) | called by muse, varscan2
- MIR519E | n.18C>A | RNA (SNP) | VAF 14/85 reads (16%) | called by mutect2, varscan2
- PXN | c.831+2174C>T | Intron (SNP) | VAF 12/26 reads (46%) | called by mutect2, varscan2
- SNORD114-5 | n.58C>T | RNA (SNP) | VAF 11/49 reads (22%) | catalogued as rs370319460; called by muse, mutect2, varscan2
- XBP1 | c.227+326_227+332del | Intron (DEL) | VAF 6/42 reads (14%) | called by pindel, varscan2
